Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4253, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4253-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Body, lesser curvature. Tumor configuration: Exophytic (polypoid). Tumor size: 11.0 x 9.0 x 2.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: 3 of 8 lymph nodes positive for metastasis. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 2193920a-acdb-4df1-a6c1-7ac6cf2e47c8 (TCGA-BR-4253.4F808990-C2CF-480B-8ACF-580269DA7DEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).